Somatic mutation profile of tumor specimen TCGA-CR-6478-01A (aliquot TCGA-CR-6478-01A-11D-1870-08) from TCGA case TCGA-CR-6478, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G3; Age at diagnosis: 66.4 years (24,244 days).
Specimen TCGA-CR-6478-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98da3ecf-b12a-40f8-8f5e-6763ab802ccd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6478-10A (Blood Derived Normal), aliquot TCGA-CR-6478-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57f6041a-07b4-46a0-88e8-6207006fc0e4

The open-access MAF lists 133 somatic variants for this specimen: 86 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 44, Nonsense Mutation 6, Intron 2, In Frame Del 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKNAD1 | c.2006G>A p.C669Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV100645553; called by muse, mutect2, varscan2
- ARMT1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.027); catalogued as COSV100939799; called by muse, mutect2, varscan2
- ART1 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99167173; called by muse, varscan2
- AWAT1 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100997203; called by muse, mutect2, varscan2
- BRWD1 | c.2975A>T p.E992V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100313456; called by muse, mutect2, varscan2
- BSN | c.2530C>T p.R844* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV56523309; called by muse, mutect2, varscan2
- CLCA4 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV99760513; called by muse, mutect2
- CLEC17A | c.585C>T p.Y195= | Splice Region (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100355358; called by muse, mutect2
- COPS4 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV100018556; called by muse, mutect2, varscan2
- CREBBP | c.4441G>A p.D1481N | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52114118; called by muse, mutect2, varscan2
- CT45A10 | c.408C>A p.C136* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | catalogued as COSV65921088; called by muse, mutect2, varscan2
- CXCL10 | c.109A>C p.N37H | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV100134083; called by muse, mutect2
- DCP1A | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs555794342, COSV99588008; called by muse, mutect2, varscan2
- DENND2D | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 11/252 reads (4%) | catalogued as COSV100718680; called by muse, mutect2
- DNAH8 | c.11846G>A p.R3949Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs770628767, COSV100545784, COSV59426779; ClinVar: uncertain significance; called by mutect2, varscan2
- DROSHA | c.3803G>A p.C1268Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV100757631; called by muse, mutect2, varscan2
- DUOX1 | c.3520G>A p.D1174N | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as COSV100368012; called by muse, mutect2, varscan2
- EBNA1BP2 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99355972; called by muse, mutect2
- ECE1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as rs1466947729, COSV99941862; called by muse, mutect2, varscan2
- EPB41L3 | c.2524C>G p.H842D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV100549249, COSV59467123; called by muse, mutect2, varscan2
- EPN3 | c.1385G>A p.S462N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99276993; called by muse, mutect2, varscan2
- FAM98A | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99479299; called by muse, mutect2
- FAT3 | c.13666C>T p.Q4556* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV53139208, COSV99966467; called by muse, mutect2, varscan2
- FNDC3A | c.1060A>G p.I354V (on ENST00000492622 / NM_001079673.2; = p.I298V on NM_014923.5) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759840570, COSV101256587; called by muse, mutect2, varscan2
- FUT10 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs17855839, COSV100161471; called by muse, mutect2, varscan2
- GOLGB1 | c.7330A>G p.T2444A | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1157728909, COSV100510907; called by muse, mutect2, varscan2
- GRK2 | c.1864C>T p.L622F | Missense Mutation (SNP) | VAF 24/385 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as rs1364285412, COSV100398485; called by muse, mutect2
- GSTA5 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV99489563; called by muse, mutect2, varscan2
- H2BC3 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV100778299; called by muse, mutect2, varscan2
- HCAR1 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775205075, COSV100811620; called by muse, mutect2
- HSD17B4 | c.1894C>T p.P632S (on ENST00000414835 / NM_001199291.3; = p.P607S on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs774766165, COSV99819850; called by muse, mutect2
- HSP90AB1 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as rs1339214249, COSV62334155, COSV62335827; called by muse, mutect2
- ICE1 | c.1979C>A p.T660N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as COSV99664832; called by muse, mutect2, varscan2
- IQCN | c.2146A>T p.M716L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs773068205, COSV101148674, COSV66574164; called by muse, mutect2, varscan2
- KLHL32 | c.23G>C p.S8T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.107); catalogued as COSV100987306; called by muse, mutect2, varscan2
- KMT2D | c.7138C>T p.Q2380* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV56429213; called by muse, mutect2, varscan2
- KRTAP5-10 | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.067); catalogued as COSV100924143; called by muse, mutect2, varscan2
- KRTAP5-10 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 92/247 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV100924144; called by muse, mutect2, varscan2
- KTI12 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100860199; called by muse, mutect2, varscan2
- LAMP5 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99855593; called by muse, mutect2, varscan2
- LRRK2 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100110274; called by muse, mutect2
- LYST | c.8266C>T p.H2756Y | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.091); catalogued as COSV101089459; called by muse, mutect2, varscan2
- MAP3K19 | c.1811A>T p.H604L | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100208593; called by muse, mutect2, varscan2
- MARCHF7 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV99373810; called by muse, mutect2, varscan2
- MED12 | c.5435A>G p.Y1812C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.984); catalogued as COSV100378104; called by muse, mutect2, varscan2
- MIA3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs764134392, COSV100719450; called by muse, mutect2, varscan2
- NRXN1 | c.3912G>A p.M1304I | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1553534743, COSV100640292; ClinVar: uncertain significance; called by muse, mutect2
- NTM | c.428C>G p.S143* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as rs1348714414, COSV100868532; called by muse, mutect2, varscan2
- OR2T6 | c.677A>C p.H226P | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as COSV100861566; called by muse, mutect2, varscan2
- OTOF | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV99717773; called by muse, mutect2, varscan2
- POLI | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as COSV99471092; called by muse, mutect2, varscan2
- PRSS1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100297991; called by muse, mutect2, varscan2
- PSMA8 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1163248396, COSV100378887, COSV57602803; called by muse, mutect2, varscan2
- PSMC2 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.98); catalogued as COSV99485307; called by muse, mutect2, varscan2
- PTCHD1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV101037341, COSV65063287; called by muse, mutect2, varscan2
- RRAGA | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100998114; called by muse, mutect2
- RTN4RL1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV100486577; called by muse, mutect2, varscan2
- RYR3 | c.2458A>G p.R820G | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV101212845; called by muse, mutect2, varscan2
- SCN9A | c.2656C>A p.Q886K (on ENST00000303354; = p.Q875K on NM_002977.3) | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM119206, COSV100312936; called by muse, mutect2
- SEC23B | c.1876T>A p.Y626N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.434); catalogued as COSV99357710; called by muse, mutect2, varscan2
- SEC31A | c.2027T>C p.L676P (on ENST00000355196 / NM_001318120.1; = p.L637P on NM_016211.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100021894; called by muse, mutect2, varscan2
- SETD1A | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755237547, COSV99353039; called by muse, varscan2
- SLC12A6 | c.3389A>T p.E1130V (on ENST00000354181 / NM_001365088.1; = p.E1079V on NM_005135.2) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99272100; called by muse, mutect2, varscan2
- SLC35F4 | c.566A>G p.Y189C (on ENST00000339762 / NM_001352015.2; = p.Y153C on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV60265917; called by muse, mutect2, varscan2
- SORCS3 | c.1219A>C p.T407P | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV100865156; called by muse, mutect2
- STKLD1 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs372995558, COSV100912031; called by muse, mutect2, varscan2
- TADA2A | c.760A>G p.M254V | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs774171350; called by muse, mutect2, varscan2
- TEX2 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.149); catalogued as COSV99367139; called by muse, mutect2
- THAP9 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV100155863, COSV56355494; called by muse, mutect2, varscan2
- TIAM2 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV100019167; called by muse, mutect2, varscan2
- TNNT1 | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV99402878; called by muse, mutect2, varscan2
- TRIM56 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100047375; called by muse, mutect2, varscan2
- TRMT13 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV100924013; called by muse, mutect2, varscan2
- USH2A | c.9148G>A p.V3050I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.15); catalogued as COSV100235267; called by muse, mutect2, varscan2
- USP30 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99980396; called by muse, mutect2
- WBP11 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99660708; called by muse, mutect2, varscan2
- YARS2 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99846104; called by muse, mutect2, varscan2
- ZC3H12C | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as rs996923785, COSV99585019; called by muse, mutect2
- ZFR | c.886_906del p.A296_A302del | In Frame Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs778993501; called by mutect2, pindel, varscan2*
- ZMYM4 | c.2873C>T p.S958F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100110551, COSV58915115; called by muse, mutect2, varscan2
- ZNF501 | c.383A>G p.H128R | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV101247107; called by muse, mutect2, varscan2
- ZNF597 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100072020; called by muse, mutect2, varscan2
- COL24A1 | c.5132T>C p.V1711A | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); called by muse, mutect2
- EDNRB | c.1218G>T p.K406N (on ENST00000377211 / NM_001201397.1; = p.K316N on NM_000115.5) | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- MOCS3 | c.583_585del p.L195del | In Frame Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- ACD | c.924C>T p.V308= (on ENST00000620338; = p.V219= on NM_022914.3) | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs374438854; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACTR1B | c.366G>A p.E122= | Silent (SNP) | VAF 30/434 reads (7%) | catalogued as COSV100008103; called by muse, mutect2
- ADGRE1 | c.1606C>T p.L536= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99165328; called by muse, mutect2, varscan2
- AHNAK | c.7395C>T p.P2465= | Silent (SNP) | VAF 26/274 reads (9%) | catalogued as COSV99947642; called by muse, mutect2
- ANKRD2 | c.553C>T p.L185= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100080870; called by muse, mutect2, varscan2
- AOX1 | c.2835A>G p.L945= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV101022001; called by muse, mutect2, varscan2
- ATG4D | c.1305T>A p.A435= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100470145; called by muse, mutect2, varscan2
- C7orf25 | c.426C>T p.I142= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV100623643; called by muse, mutect2
- CPAMD8 | c.2784G>A p.L928= (on ENST00000651564; = p.L881= on NM_015692.5) | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV101488518; called by muse, mutect2, varscan2
- EPB41L3 | c.2523G>T p.V841= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100549253, COSV59460231; called by muse, mutect2, varscan2
- EPHA5 | c.2952G>A p.E984= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99899084; called by muse, mutect2, varscan2
- FAM13C | c.1140C>T p.G380= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs776976417, COSV99513918; called by muse, mutect2, varscan2
- FER1L6 | c.5049G>A p.K1683= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV101205890; called by muse, mutect2
- GOT1 | c.18C>T p.V6= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV100981767; called by muse, mutect2, varscan2
- H2AC11 | c.210G>A p.A70= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV100345754; called by muse, mutect2, varscan2
- JCAD | c.2898C>T p.D966= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs754512845, COSV64759428; called by muse, mutect2, varscan2
- KIF21A | c.2922G>A p.E974= (on ENST00000361418 / NM_001378440.1; = p.E961= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/183 reads (7%) | catalogued as rs1244501187, COSV100735475; called by muse, mutect2
- KRR1 | c.16C>T p.L6= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs1372196370, COSV99974808; called by muse, mutect2
- LANCL2 | c.525C>T p.V175= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99634835; called by muse, mutect2, varscan2
- LRPAP1 | c.573G>A p.E191= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99578952; called by muse, mutect2
- MAP4K3 | c.2340C>T p.T780= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99810440; called by muse, mutect2, varscan2
- MECR | c.18C>T p.T6= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99747075; called by muse, mutect2
- MPP2 | c.1467G>T p.V489= (on ENST00000461854 / NM_001278372.2; = p.V465= on NM_005374.5) | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV99290425; called by muse, mutect2, varscan2
- MS4A4A | c.123A>T p.G41= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV59702882; called by muse, mutect2
- MTFP1 | c.444C>T p.L148= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99840875; called by muse, varscan2
- NTN3 | c.564C>T p.S188= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs770034439, COSV99565007; called by muse, mutect2, varscan2
- OR7A17 | c.276C>T p.I92= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100541621; called by muse, mutect2, varscan2
- PCDHA4 | c.1671C>T p.D557= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1451689285, COSV63545662; called by muse, mutect2, varscan2
- PDE3A | c.2298T>C p.Y766= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100762158; called by muse, mutect2, varscan2
- POLQ | c.5379C>T p.F1793= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV99952302; called by muse, mutect2
- PPP1R12B | c.2385C>T p.I795= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99294886; called by muse, mutect2, varscan2
- RANBP10 | c.552G>A p.K184= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as rs1359227478, COSV100449313, COSV58158517; called by muse, mutect2
- SOX17 | c.1107C>T p.F369= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs201582946, COSV99810605, COSV99810767; called by muse, mutect2, varscan2
- STAB2 | c.2508C>T p.F836= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV101185987; called by muse, mutect2, varscan2
- TET2 | c.1329A>G p.T443= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs999684061, COSV99483000; called by muse, mutect2, varscan2
- TFDP2 | c.654G>A p.Q218= (on ENST00000489671 / NM_001178139.2; = p.Q158= on NM_006286.5) | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as rs764902177, COSV100050915; called by muse, mutect2, varscan2
- TNS4 | c.1524C>A p.I508= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV99563853; called by muse, mutect2, varscan2
- TP53I13 | c.162C>T p.Y54= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99838214; called by muse, mutect2, varscan2
- TTC7A | c.2508C>T p.F836= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1057436611, COSV99766475; called by muse, mutect2, varscan2
- UROD | c.246C>T p.I82= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as HD030004, COSV99870212; called by muse, mutect2, varscan2
- USP34 | c.5748T>A p.P1916= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as rs1415074215, COSV101277047; called by muse, varscan2
- VPS41 | c.1566G>A p.K522= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV59645682, COSV59650758; called by muse, mutect2, varscan2
- ZADH2 | c.330T>C p.S110= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as COSV100463409; called by muse, mutect2
- ZNF536 | c.3279C>T p.S1093= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs147863190; called by muse, mutect2, varscan2
- DBI | c.10-269G>A | Intron (SNP) | VAF 15/133 reads (11%) | catalogued as COSV100275900; called by muse, mutect2, varscan2
- RPL23AP42 | n.239C>T | RNA (SNP) | VAF 8/88 reads (9%) | catalogued as rs1389912749; called by muse, mutect2
- SF3B3 | c.826-287C>A | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100209938; called by muse, mutect2, varscan2
